Somatic mutation profile of tumor specimen 0DX7FW from CCDI case PBCPMM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain stem; Age at diagnosis: 6.6 years (2,428 days).
Specimen 0DX7FW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0942726b-dc99-4d45-81a9-c826a1e30642.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DX7EQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ac1a26d-a0ed-47c0-bc29-0a41efc795ec

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 84/368 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by mutect2, varscan2
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 153/411 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.4968C>G p.S1656R | Missense Mutation (SNP) | VAF 81/359 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EXOC2 | c.2221A>G p.I741V | Missense Mutation (SNP) | VAF 114/579 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HOXB3 | c.347A>T p.K116M | Missense Mutation (SNP) | VAF 26/778 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); called by muse, mutect2
- PRKCD | c.1358A>G p.Y453C | Missense Mutation (SNP) | VAF 37/338 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SOX10 | c.587_599del p.E196Afs*86 | Frame Shift Del (DEL) | VAF 60/647 reads (9%) | called by mutect2, pindel
- TRAPPC8 | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 37/355 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- UMODL1 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 51/334 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARL14EPL | c.111G>A p.R37= | Silent (SNP) | VAF 14/365 reads (4%) | called by muse, mutect2
- MAPK7 | c.633C>T p.P211= | Silent (SNP) | VAF 40/536 reads (7%) | catalogued as rs774285349, COSV100218927; called by muse, mutect2
- EPPIN-WFDC6 | c.-68A>G | 5'UTR (SNP) | VAF 50/176 reads (28%) | called by muse, mutect2, varscan2
